FM case AD13971 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/36714f3a-35a7-408e-ac71-e727626995b1

Female, 56.7 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the bladder; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
